Somatic mutation profile of tumor specimen 0DU1X9 from CCDI case PBCKKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 3.3 years (1,216 days).
Specimen 0DU1X9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cee5c1da-13b8-4f0f-b56d-0cd9c41ee9c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU1WA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b817734f-0059-4c9e-adff-a74d1fee0ee8

The open-access MAF lists 12 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, Silent 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOX30 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 116/2836 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.285); catalogued as rs1236770031, COSV99398839; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 70/1924 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 50/1287 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- TSPYL2 | c.1538A>G p.D513G | Missense Mutation (SNP) | VAF 933/1940 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY4 | c.1206C>T p.G402= | Silent (SNP) | VAF 124/2462 reads (5%) | catalogued as rs768054869; called by muse, mutect2
- DSG2 | c.2037C>A p.G679= | Silent (SNP) | VAF 910/2193 reads (41%) | called by mutect2, varscan2
- FER | c.564G>A p.A188= | Silent (SNP) | VAF 391/1373 reads (28%) | catalogued as rs764496636, COSV99812229; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 36/1112 reads (3%) | called by muse, mutect2
- EEF1D | c.-7-2254G>A | Intron (SNP) | VAF 558/1203 reads (46%) | catalogued as rs1191022997; called by muse, mutect2, varscan2
- PPP1R37 | c.988-97G>A | Intron (SNP) | VAF 20/541 reads (4%) | catalogued as rs1437838122; called by muse, mutect2
- RPL14 | c.3+203C>A | Intron (SNP) | VAF 52/946 reads (5%) | called by muse, mutect2
- SNTG2 | c.*41G>A | 3'UTR (SNP) | VAF 419/647 reads (65%) | catalogued as rs756915320; called by muse, mutect2, varscan2
